Gene-level copy-number profile of tumor specimen TCGA-EB-A430-01A from TCGA case TCGA-EB-A430, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.1 years (30,344 days).
Specimen TCGA-EB-A430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.1a8e93cb-79d8-4f05-a62d-5447f1e260bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80a7a746-23ae-4edf-ac2c-89f4808c8073

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,091; copy number 2: 41,495; copy number 3: 2,085; copy number 4: 3,750; copy number 5: 209; copy number 6: 187.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A430-01A-11D-A24Q-01): tumor purity 0.72, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 396 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,008,420–153,150,890, 123 genes, copy number 6 (broad region; genes not listed).
- chr1:196,225,779–204,685,738, 202 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:217,426,992–217,871,696, 4 genes, copy number 5: GPATCH2, SPATA17, SPATA17-AS1, UBBP2.
- chr1:223,863,726–226,542,729, 67 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
